Somatic mutation profile of tumor specimen 0DVSBT from CCDI case PBCMRN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.1 years (406 days).
Specimen 0DVSBT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4729283-8662-4a27-b0cc-f6ec5e9379c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSC6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aed1e693-6a5b-4dd4-bbf8-cbb2d81a3751

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF18 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 80/429 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758902974, COSV51126535; called by muse, mutect2, varscan2
- MSL2 | c.1366C>A p.P456T | Missense Mutation (SNP) | VAF 258/948 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs772841039; called by mutect2, varscan2
- NPTX1 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 262/543 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs779729063, COSV60774385; called by muse, mutect2, varscan2
- TRIM6 | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1227080487; called by muse, mutect2, varscan2
- CCDC197 | c.555C>T p.C185= | Silent (SNP) | VAF 48/586 reads (8%) | called by muse, mutect2
